Somatic mutation profile of tumor specimen MMRF_2089_3_PB_CD138pos (aliquot MMRF_2089_3_PB_CD138pos_T1_KHS5U_L14848) from MMRF case MMRF_2089, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 66.9 years (24,417 days).
Specimen MMRF_2089_3_PB_CD138pos: Sample type: Recurrent Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ec52f8a8-58ef-4c86-8fbb-dc12d410d402.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2089_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2089_1_PB_WBC_C3_KHS5U_L08822; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0ca1926c-83f5-4bf9-b691-f99b6157d79f

The open-access MAF lists 487 somatic variants for this specimen: 202 protein-altering or splice-affecting, 60 silent, 225 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 166, 3'UTR 139, Silent 60, Intron 52, 5'UTR 15, Nonsense Mutation 14, Frame Shift Del 10, RNA 8, Splice Site 6, 5'Flank 6, 3'Flank 4, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 56/140 reads (40%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.841G>A p.D281N | Missense Mutation (SNP) | VAF 42/87 reads (48%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs764146326, CD137626, CM076566, CM153816, COSV52671054, COSV52674651, COSV52678614; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- ACAN | c.6701T>A p.L2234Q | Missense Mutation (SNP) | VAF 145/290 reads (50%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.977); catalogued as COSV100718699; called by muse, mutect2, varscan2
- ADGRD1 | c.1079A>G p.H360R | Missense Mutation (SNP) | VAF 67/187 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.949); catalogued as rs746975895; called by muse, mutect2, varscan2
- AMOTL1 | c.963G>A p.M321I | Missense Mutation (SNP) | VAF 96/335 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV100133830; called by muse, mutect2, varscan2
- ANKRD42 | c.1030T>C p.F344L | Missense Mutation (SNP) | VAF 11/200 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.883); catalogued as COSV52614252; called by muse, mutect2
- APOA2 | c.277C>T p.L93F | Missense Mutation (SNP) | VAF 68/317 reads (21%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as rs1215900467; called by muse, mutect2, varscan2
- BTG1 | c.85A>T p.K29* | Nonsense Mutation (SNP) | VAF 62/168 reads (37%) | catalogued as COSV55458809; called by muse, varscan2
- C1orf94 | c.1199G>T p.G400V (on ENST00000488417 / NM_001134734.2; = p.G210V on NM_032884.5) | Missense Mutation (SNP) | VAF 94/239 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100974946; called by muse, mutect2, varscan2
- C3orf62 | c.259G>C p.E87Q | Missense Mutation (SNP) | VAF 56/221 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.628); catalogued as COSV55539998; called by muse, mutect2, varscan2
- CAT | c.1333G>A p.A445T | Missense Mutation (SNP) | VAF 61/221 reads (28%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs749536831; called by muse, mutect2, varscan2
- CDH7 | c.2245G>C p.D749H | Missense Mutation (SNP) | VAF 103/217 reads (47%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.606); catalogued as COSV59883694; called by muse, mutect2, varscan2
- COA3 | c.211A>C p.I71L | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs748728709, COSV55904088; called by muse, mutect2, varscan2
- COL27A1 | c.2512G>A p.G838S | Missense Mutation (SNP) | VAF 140/246 reads (57%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV61926137; called by muse, varscan2
- CUZD1 | c.454C>G p.P152A | Missense Mutation (SNP) | VAF 43/164 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.053); catalogued as rs558554477; called by muse, mutect2, varscan2
- DFFA | c.526dup p.Q176Pfs*5 | Frame Shift Ins (INS) | VAF 39/146 reads (27%) | catalogued as rs755703182; called by mutect2, pindel, varscan2
- DNAH5 | c.6661G>C p.E2221Q | Missense Mutation (SNP) | VAF 52/208 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.317); catalogued as COSV54235819; called by muse, mutect2, varscan2
- DYNC2H1 | c.6153G>C p.W2051C | Missense Mutation (SNP) | VAF 54/218 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100520050; called by muse, mutect2, varscan2
- FEN1 | c.744C>A p.D248E | Missense Mutation (SNP) | VAF 9/171 reads (5%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs1415571176; called by muse, mutect2
- FLG | c.2561G>T p.G854V | Missense Mutation (SNP) | VAF 96/250 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as rs373305550; called by muse, mutect2, varscan2
- GMPR | c.179C>T p.T60M | Missense Mutation (SNP) | VAF 55/256 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1162015376; called by muse, mutect2, varscan2
- HTR1F | c.834G>A p.W278* | Nonsense Mutation (SNP) | VAF 21/391 reads (5%) | catalogued as COSV60389673; called by muse, mutect2
- IGHV2-70 | c.314A>C p.N105T | Missense Mutation (SNP) | VAF 36/70 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.072); catalogued as rs372581706; called by muse, varscan2
- IGHV2-70 | c.310A>T p.T104S | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (1); PolyPhen probably damaging (0.989); catalogued as rs368647772; called by muse, varscan2
- IGHV2-70 | c.155del p.G52Efs*4 | Frame Shift Del (DEL) | VAF 56/119 reads (47%) | catalogued as rs757190616; called by pindel, varscan2
- IGHV2-70 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.876); catalogued as rs534553794; called by muse, varscan2
- IGLV3-1 | c.97C>G p.P33A | Missense Mutation (SNP) | VAF 93/182 reads (51%) | SIFT tolerated (0.76); PolyPhen benign (0.166); catalogued as rs573884769; called by muse, mutect2, varscan2
- KCNC4 | c.777G>T p.E259D | Missense Mutation (SNP) | VAF 12/310 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV63924856; called by muse, mutect2
- MAGEL2 | c.3559C>T p.R1187* | Nonsense Mutation (SNP) | VAF 153/261 reads (59%) | catalogued as rs368965952, COSV100045884, COSV100046025; called by muse, mutect2, varscan2
- MAP1A | c.2592G>C p.K864N | Missense Mutation (SNP) | VAF 68/278 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100288595; called by muse, mutect2, varscan2
- MATN2 | c.799G>A p.G267S | Missense Mutation (SNP) | VAF 23/377 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1266765851; called by muse, mutect2
- MUC12 | c.394C>T p.L132F | Missense Mutation (SNP) | VAF 40/122 reads (33%) | SIFT tolerated, low confidence (0.06); catalogued as rs1256983713; called by muse, mutect2, varscan2
- MYCBP2 | c.12823G>A p.D4275N (on ENST00000357337; = p.D4313N on NM_015057.5) | Missense Mutation (SNP) | VAF 173/200 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV62044146; called by muse, mutect2, varscan2
- NCAPG2 | c.2579C>G p.S860C | Missense Mutation (SNP) | VAF 9/114 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.524); catalogued as rs1334499369; called by muse, mutect2
- NUP214 | c.3295C>T p.R1099W | Missense Mutation (SNP) | VAF 53/195 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1303316975; called by muse, mutect2, varscan2
- OR5H2 | c.181C>A p.H61N | Missense Mutation (SNP) | VAF 16/420 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV62351327; called by muse, mutect2
- PARP14 | c.4402G>A p.D1468N | Missense Mutation (SNP) | VAF 61/256 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as rs564004211; called by muse, mutect2, varscan2
- PDCD11 | c.4291G>C p.G1431R | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV63932868; called by muse, mutect2, varscan2
- PLXDC2 | c.706G>C p.D236H | Missense Mutation (SNP) | VAF 15/214 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV65909929; called by muse, mutect2
- PLXNB1 | c.3817C>T p.R1273C | Missense Mutation (SNP) | VAF 37/230 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs777440373, COSV56486750; called by muse, mutect2, varscan2
- PPP1R3C | c.60G>A p.M20I | Missense Mutation (SNP) | VAF 40/106 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as rs765370918; called by muse, mutect2, varscan2
- PTPRC | c.1565T>C p.V522A | Missense Mutation (SNP) | VAF 53/214 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.11); catalogued as rs762391496, COSV100723348; called by muse, mutect2, varscan2
- PTPRZ1 | c.767C>T p.S256F | Missense Mutation (SNP) | VAF 22/380 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66435909; called by muse, mutect2
- RAB10 | c.574G>A p.V192M | Missense Mutation (SNP) | VAF 65/493 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.063); catalogued as rs149788536; called by muse, mutect2, varscan2
- RINL | c.1499T>C p.F500S (on ENST00000591812 / NM_001195833.2; = p.F386S on NM_198445.4) | Missense Mutation (SNP) | VAF 54/88 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs758854340; called by muse, varscan2
- RIPOR1 | c.1262G>A p.R421H (on ENST00000379312 / NM_001193522.2; = p.R417H on NM_024519.4) | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs762938282; called by muse, mutect2
- RYR3 | c.4118A>T p.D1373V | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs755136349; called by muse, mutect2, varscan2
- SLC1A5 | c.173C>T p.T58I | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778524513; called by muse, mutect2, varscan2
- SNTG2 | c.1606A>G p.M536V | Missense Mutation (SNP) | VAF 53/137 reads (39%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs371161023; called by muse, mutect2, varscan2
- SVOPL | c.434C>T p.T145M | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.69); catalogued as rs139868586; called by muse, mutect2, varscan2
- TRABD | c.672C>T p.S224= | Splice Region (SNP) | VAF 34/112 reads (30%) | catalogued as rs763947053; called by muse, mutect2, varscan2
- TRAF1 | c.97C>T p.P33S | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.275); catalogued as rs1417682125; called by muse, mutect2, varscan2
- TRRAP | c.5867C>T p.T1956I (on ENST00000359863 / NM_001244580.1; = p.T1938I on NM_003496.3) | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.067); catalogued as rs782485850; called by muse, mutect2, varscan2
- TTN | c.88630C>T p.R29544C (on ENST00000591111; = p.R22120C on NM_003319.4) | Missense Mutation (SNP) | VAF 17/202 reads (8%) | PolyPhen probably damaging (0.998); catalogued as rs768852545; called by muse, mutect2
- UEVLD | c.305A>G p.H102R | Missense Mutation (SNP) | VAF 92/288 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1308377012; called by muse, mutect2, varscan2
- UHRF1BP1L | c.3269G>A p.C1090Y | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV54440839; called by muse, mutect2
- WNK3 | c.3440C>T p.S1147F | Missense Mutation (SNP) | VAF 80/92 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV63614176; called by muse, mutect2, varscan2
- ZNF527 | c.789A>T p.Q263H | Missense Mutation (SNP) | VAF 16/161 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.496); catalogued as COSV62229722; called by muse, mutect2, varscan2
- ZNF679 | c.1210G>T p.G404* | Nonsense Mutation (SNP) | VAF 67/194 reads (35%) | catalogued as COSV55378362; called by muse, mutect2, varscan2
- ZNF679 | c.1211G>T p.G404V | Missense Mutation (SNP) | VAF 67/194 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99738433; called by muse, mutect2, varscan2
- ZNF7 | c.851G>A p.G284E | Missense Mutation (SNP) | VAF 271/299 reads (91%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.874); catalogued as rs1319987786; called by muse, mutect2, varscan2
- ZNHIT6 | c.916-1G>A p.X306_splice | Splice Site (SNP) | VAF 4/28 reads (14%) | catalogued as rs776733079, COSV65327423; called by mutect2, varscan2
- A2ML1 | c.1144G>C p.G382R | Missense Mutation (SNP) | VAF 95/229 reads (41%) | SIFT tolerated (0.35); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ABCA4 | c.4783A>T p.T1595S | Missense Mutation (SNP) | VAF 36/72 reads (50%) | SIFT tolerated (0.9); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ACSM2B | c.383G>T p.R128L | Missense Mutation (SNP) | VAF 36/74 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AFF2 | c.2105A>T p.K702M | Missense Mutation (SNP) | VAF 88/101 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- AGFG2 | c.633G>C p.Q211H | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ALLC | c.55T>C p.F19L | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- AMBRA1 | c.3525G>T p.M1175I (on ENST00000458649 / NM_001367468.1; = p.M1085I on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/172 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.878); called by muse, mutect2
- ANKK1 | c.1705G>C p.A569P | Missense Mutation (SNP) | VAF 9/185 reads (5%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.588); called by muse, mutect2
- ANKRD17 | c.4779C>G p.Y1593* | Nonsense Mutation (SNP) | VAF 59/115 reads (51%) | called by muse, mutect2, varscan2
- ANKRD26 | c.3568G>C p.E1190Q | Missense Mutation (SNP) | VAF 7/119 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.079); called by muse, mutect2
- AP3B2 | c.1681C>G p.Q561E | Missense Mutation (SNP) | VAF 12/174 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.709); called by muse, mutect2
- APH1A | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 45/239 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.318); called by muse, mutect2, varscan2
- ARHGAP11A | c.766G>C p.D256H | Missense Mutation (SNP) | VAF 151/873 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); called by muse, mutect2, varscan2
- B4GALT6 | c.354C>A p.F118L | Missense Mutation (SNP) | VAF 108/181 reads (60%) | SIFT tolerated (0.77); PolyPhen benign (0); called by muse, mutect2, varscan2
- C10orf71 | c.1136C>A p.P379H | Missense Mutation (SNP) | VAF 10/164 reads (6%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.911); called by muse, mutect2
- CATSPERG | c.1839G>A p.M613I | Missense Mutation (SNP) | VAF 60/293 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- CCDC60 | c.1268T>C p.F423S | Missense Mutation (SNP) | VAF 11/173 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.439); called by muse, mutect2
- CCNE1 | c.1111-2A>T p.X371_splice | Splice Site (SNP) | VAF 16/196 reads (8%) | called by muse, mutect2
- CD207 | c.122C>G p.T41R | Missense Mutation (SNP) | VAF 35/117 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.387); called by muse, mutect2, varscan2
- CHD1 | c.669A>T p.E223D | Missense Mutation (SNP) | VAF 53/126 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CISH | c.524G>A p.S175N (on ENST00000348721 / NM_145071.4; = p.S192N on NM_013324.6) | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT tolerated (0.35); PolyPhen benign (0.201); called by muse, mutect2
- CLK3 | c.1750C>T p.L584F (on ENST00000395066 / NM_001130028.1; = p.L436F on NM_003992.4) | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.267); called by muse, mutect2, varscan2
- CMYA5 | c.9854A>T p.K3285M | Missense Mutation (SNP) | VAF 72/164 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- COL18A1 | c.2493+2T>G p.X831_splice (on ENST00000359759 / NM_130444.3; = p.X596_splice on NM_030582.4) | Splice Site (SNP) | VAF 53/211 reads (25%) | called by muse, mutect2, varscan2
- CTNNA2 | c.1286T>A p.V429E | Missense Mutation (SNP) | VAF 64/238 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); called by muse, varscan2
- CTSK | c.189G>T p.E63D | Missense Mutation (SNP) | VAF 83/335 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- CTSV | c.572A>G p.K191R | Missense Mutation (SNP) | VAF 15/424 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.096); called by muse, mutect2
- CTSV | c.113G>A p.R38K | Missense Mutation (SNP) | VAF 138/435 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DCAF12 | c.229A>T p.S77C | Missense Mutation (SNP) | VAF 6/113 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2
- DCAF5 | c.748G>A p.A250T | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- DESI2 | c.366A>T p.K122N | Missense Mutation (SNP) | VAF 8/131 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.076); called by muse, mutect2
- DNAH9 | c.721T>G p.L241V | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- DNAH9 | c.7916A>T p.N2639I | Missense Mutation (SNP) | VAF 23/294 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.148); called by muse, mutect2
- DNAJC13 | c.1188_1190del p.F396_S397delinsL | In Frame Del (DEL) | VAF 44/154 reads (29%) | called by mutect2, pindel, varscan2
- DNM3 | c.1195A>T p.R399W | Missense Mutation (SNP) | VAF 9/117 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- DPYSL2 | c.251G>A p.R84Q | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DPYSL3 | c.619C>T p.Q207* | Nonsense Mutation (SNP) | VAF 24/49 reads (49%) | called by muse, mutect2, varscan2
- DRAXIN | c.200G>C p.W67S | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- DSC1 | c.748A>T p.T250S | Missense Mutation (SNP) | VAF 15/191 reads (8%) | SIFT tolerated (0.84); PolyPhen benign (0.003); called by muse, mutect2
- DSC2 | c.1109A>C p.D370A | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- DUSP7 | c.419C>T p.T140M | Missense Mutation (SNP) | VAF 54/149 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- EFCAB8 | c.2818G>A p.V940I | Missense Mutation (SNP) | VAF 18/180 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.101); called by muse, mutect2
- EPHA2 | c.964T>C p.S322P | Missense Mutation (SNP) | VAF 12/206 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2
- EXOC6B | c.1072T>G p.L358V | Missense Mutation (SNP) | VAF 9/212 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); called by muse, mutect2
- F13A1 | c.1676C>T p.T559I | Missense Mutation (SNP) | VAF 65/293 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- FRYL | c.1204A>G p.T402A | Missense Mutation (SNP) | VAF 74/165 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- GFPT2 | c.1171G>A p.E391K | Missense Mutation (SNP) | VAF 13/150 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- GNPAT | c.1288C>A p.P430T | Missense Mutation (SNP) | VAF 44/268 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GRAMD4 | c.1136G>A p.C379Y | Missense Mutation (SNP) | VAF 13/127 reads (10%) | SIFT tolerated (0.61); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- HDAC5 | c.2842A>T p.I948F | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- HK1 | c.1265A>G p.Q422R | Missense Mutation (SNP) | VAF 56/145 reads (39%) | SIFT tolerated (0.88); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- HLA-DPB1 | c.196C>T p.R66C | Missense Mutation (SNP) | VAF 72/236 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- HYKK | c.1047T>A p.F349L | Missense Mutation (SNP) | VAF 27/370 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2
- IGHV2-70D | c.347G>A p.C116Y | Missense Mutation (SNP) | VAF 14/21 reads (67%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- IGKV4-1 | c.136del p.S46Afs*14 | Frame Shift Del (DEL) | VAF 34/60 reads (57%) | called by pindel, varscan2
- INTS10 | c.769G>C p.E257Q | Missense Mutation (SNP) | VAF 94/202 reads (47%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.447); called by muse, mutect2, varscan2
- ITGA10 | c.2057C>T p.S686F | Missense Mutation (SNP) | VAF 21/335 reads (6%) | SIFT tolerated (0.85); PolyPhen benign (0.147); called by muse, mutect2
- JRK | c.233G>C p.R78P | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- KBTBD3 | c.1516C>A p.P506T | Missense Mutation (SNP) | VAF 62/195 reads (32%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- KLHDC7B | c.1573C>T p.P525S (on ENST00000395676; = p.P1166S on NM_138433.5) | Missense Mutation (SNP) | VAF 80/180 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.183); called by muse, mutect2
- KMT2A | c.5685A>T p.Q1895H | Missense Mutation (SNP) | VAF 20/388 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.063); called by muse, mutect2
- LRIF1 | c.338A>G p.D113G | Missense Mutation (SNP) | VAF 108/243 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- LRP2 | c.8088T>A p.N2696K | Missense Mutation (SNP) | VAF 47/100 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- LRRC74A | c.878C>T p.A293V | Missense Mutation (SNP) | VAF 30/299 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- LRTOMT | c.125del p.K42Sfs*9 | Frame Shift Del (DEL) | VAF 13/43 reads (30%) | called by mutect2, pindel, varscan2
- LRWD1 | c.1625T>G p.V542G | Missense Mutation (SNP) | VAF 41/141 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- LSM14A | c.270C>G p.D90E | Missense Mutation (SNP) | VAF 27/340 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- MACF1 | c.19546G>T p.V6516F (on ENST00000372915; = p.V4561F on NM_012090.5) | Missense Mutation (SNP) | VAF 24/301 reads (8%) | called by muse, mutect2
- MACROD1 | c.930C>A p.D310E | Missense Mutation (SNP) | VAF 33/119 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.333); called by muse, mutect2, varscan2
- MAMDC4 | c.917G>A p.S306N | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); called by muse, mutect2
- MTHFSD | c.443-1G>C p.X148_splice (on ENST00000360900 / NM_001159377.2; = p.X147_splice on NM_022764.3 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 16/184 reads (9%) | called by muse, mutect2
- MYH4 | c.2754A>T p.Q918H | Missense Mutation (SNP) | VAF 38/116 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- NARF | c.688G>A p.D230N | Missense Mutation (SNP) | VAF 62/183 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NECAP1 | c.167C>G p.A56G | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- NOSTRIN | c.1120G>A p.E374K (on ENST00000317647 / NM_001039724.4; = p.E296K on NM_052946.3) | Missense Mutation (SNP) | VAF 19/276 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.401); called by muse, mutect2
- NPTN | c.667G>A p.V223I | Missense Mutation (SNP) | VAF 8/101 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2
- NUP98 | c.3081T>A p.C1027* (on ENST00000359171 / NM_001365126.1; = p.C1010* on NM_016320.5 and 4 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 82/268 reads (31%) | called by muse, mutect2, varscan2
- NYAP1 | c.592del p.R198Gfs*5 | Frame Shift Del (DEL) | VAF 73/292 reads (25%) | called by mutect2, pindel, varscan2
- OR5AC2 | c.914G>A p.R305K | Missense Mutation (SNP) | VAF 20/414 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- OSMR | c.797G>A p.G266E | Missense Mutation (SNP) | VAF 46/189 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- PAPLN | c.2773C>T p.Q925* (on ENST00000554301; = p.Q898* on NM_173462.4) | Nonsense Mutation (SNP) | VAF 54/118 reads (46%) | called by muse, mutect2, varscan2
- PCDHGA5 | c.1770G>T p.K590N | Missense Mutation (SNP) | VAF 38/66 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PGAM5 | c.507A>T p.K169N | Missense Mutation (SNP) | VAF 46/92 reads (50%) | SIFT tolerated (0.34); PolyPhen benign (0.181); called by muse, mutect2, varscan2
- PITPNM1 | c.3635G>A p.G1212D | Missense Mutation (SNP) | VAF 32/284 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.307); called by muse, mutect2, varscan2
- PKHD1 | c.7688G>A p.S2563N | Missense Mutation (SNP) | VAF 21/248 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2
- PKHD1L1 | c.12017G>A p.S4006N | Missense Mutation (SNP) | VAF 65/244 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PLCB1 | c.2486del p.A829Vfs*2 | Frame Shift Del (DEL) | VAF 91/233 reads (39%) | called by mutect2, pindel, varscan2
- PNPLA1 | c.530G>T p.G177V (on ENST00000394571 / NM_001374623.1; = p.G82V on NM_173676.2) | Missense Mutation (SNP) | VAF 14/272 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); called by muse, mutect2
- POLE | c.1886C>T p.A629V | Missense Mutation (SNP) | VAF 62/127 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PPIC | c.463_478del p.W155Mfs*11 | Frame Shift Del (DEL) | VAF 29/108 reads (27%) | called by mutect2, pindel, varscan2
- PPM1J | c.336T>A p.N112K | Missense Mutation (SNP) | VAF 25/257 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); called by muse, mutect2
- PRLH | c.47T>A p.L16Q | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- PYDC2 | c.281T>C p.M94T | Missense Mutation (SNP) | VAF 109/396 reads (28%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RAB11FIP3 | c.835G>A p.V279I | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RABEP2 | c.949C>A p.Q317K | Missense Mutation (SNP) | VAF 44/92 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- RFX6 | c.121C>G p.P41A | Missense Mutation (SNP) | VAF 19/253 reads (8%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); called by muse, mutect2
- RGSL1 | c.626A>G p.H209R | Missense Mutation (SNP) | VAF 138/254 reads (54%) | SIFT tolerated (0.74); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- RINL | c.1504dup p.A502Gfs*51 (on ENST00000591812 / NM_001195833.2; = p.A388Gfs*51 on NM_198445.4) | Frame Shift Ins (INS) | VAF 52/120 reads (43%) | called by pindel, varscan2
- RNF217-AS1 | n.384T>G | Splice Region (SNP) | VAF 70/174 reads (40%) | called by muse, mutect2, varscan2
- SCN4A | c.1069G>A p.A357T | Missense Mutation (SNP) | VAF 41/158 reads (26%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.64); called by muse, mutect2, varscan2
- SCN5A | c.33C>G p.S11R | Missense Mutation (SNP) | VAF 51/149 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- SEL1L2 | c.1892T>A p.F631Y | Missense Mutation (SNP) | VAF 12/298 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.175); called by muse, mutect2
- SEPTIN8 | c.1311G>T p.Q437H | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- SERPINB1 | c.880C>T p.Q294* | Nonsense Mutation (SNP) | VAF 204/289 reads (71%) | called by muse, mutect2, varscan2
- SERPINB4 | c.859T>A p.F287I | Missense Mutation (SNP) | VAF 23/209 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- SETBP1 | c.1891A>T p.K631* | Nonsense Mutation (SNP) | VAF 20/204 reads (10%) | called by muse, mutect2
- SHROOM4 | c.2216C>A p.A739E | Missense Mutation (SNP) | VAF 53/66 reads (80%) | SIFT tolerated (0.25); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- SIAH2 | c.257A>C p.Y86S | Missense Mutation (SNP) | VAF 67/235 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- SLC25A44 | c.17A>G p.N6S | Missense Mutation (SNP) | VAF 27/754 reads (4%) | SIFT tolerated (0.38); PolyPhen benign (0.079); called by muse, mutect2
- SLC37A1 | c.959_973del p.F320_K325delins* | Nonsense Mutation (DEL) | VAF 16/84 reads (19%) | called by mutect2, pindel, varscan2
- SRRM4 | c.968A>T p.N323I | Missense Mutation (SNP) | VAF 11/169 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); called by muse, mutect2
- TDRD5 | c.200G>T p.C67F | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- TGIF1 | c.611del p.P204Qfs*30 (on ENST00000330513 / NM_001374396.1; = p.P224Qfs*30 on NM_003244.4) | Frame Shift Del (DEL) | VAF 110/368 reads (30%) | called by mutect2, pindel, varscan2
- TIPARP | c.1948G>C p.E650Q | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); called by muse, varscan2
- TMCC2 | c.2084G>A p.W695* | Nonsense Mutation (SNP) | VAF 24/184 reads (13%) | called by muse, mutect2, varscan2
- TMEM237 | c.1186G>T p.E396* (on ENST00000409883 / NM_001044385.3; = p.E388* on NM_152388.4) | Nonsense Mutation (SNP) | VAF 17/344 reads (5%) | called by muse, mutect2
- TNFRSF1B | c.308-2A>T p.X103_splice | Splice Site (SNP) | VAF 7/184 reads (4%) | called by muse, mutect2
- TNS1 | c.4106C>T p.S1369F | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TOR1B | c.641+1G>T p.X214_splice | Splice Site (SNP) | VAF 12/116 reads (10%) | called by muse, mutect2, varscan2
- TP53 | c.894_910del p.E298Dfs*2 | Frame Shift Del (DEL) | VAF 42/157 reads (27%) | called by pindel, varscan2
- TRMT11 | c.113C>A p.A38D | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- TSC22D1 | c.3055C>G p.Q1019E (on ENST00000458659 / NM_183422.4; = p.Q90E on NM_006022.4) | Missense Mutation (SNP) | VAF 46/48 reads (96%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- TSPAN19 | c.296T>C p.V99A | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.64); called by muse, mutect2, varscan2
- TYW1 | c.499del p.T167Lfs*3 | Frame Shift Del (DEL) | VAF 109/312 reads (35%) | called by mutect2, pindel, varscan2
- UBXN10 | c.752T>A p.F251Y | Missense Mutation (SNP) | VAF 98/321 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- USP43 | c.190G>C p.A64P | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- XPOT | c.1168A>G p.N390D | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT tolerated (0.4); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZAP70 | c.1329C>A p.H443Q | Missense Mutation (SNP) | VAF 22/168 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZBTB16 | c.575G>T p.G192V | Missense Mutation (SNP) | VAF 75/285 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- ZBTB21 | c.3000_3001delinsT p.E1000Dfs*97 | Frame Shift Del (DEL) | VAF 27/172 reads (16%) | called by pindel, varscan2*
- ZBTB26 | c.1275A>T p.K425N | Missense Mutation (SNP) | VAF 66/242 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- ZC3H12D | c.802T>A p.Y268N | Missense Mutation (SNP) | VAF 66/144 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZFHX4 | c.355T>A p.L119I | Missense Mutation (SNP) | VAF 27/327 reads (8%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.225); called by muse, mutect2
- ZNF3 | c.862G>A p.E288K | Missense Mutation (SNP) | VAF 40/131 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- ZNF415 | c.688C>G p.H230D | Missense Mutation (SNP) | VAF 83/230 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ZNF605 | c.1235A>G p.Q412R | Missense Mutation (SNP) | VAF 63/132 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ZNF611 | c.1570A>T p.S524C | Missense Mutation (SNP) | VAF 46/275 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF727 | c.505A>T p.R169* | Nonsense Mutation (SNP) | VAF 108/257 reads (42%) | called by muse, mutect2, varscan2
- ZNF880 | c.632C>G p.P211R | Missense Mutation (SNP) | VAF 49/224 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- ZSCAN32 | c.10G>T p.V4L (on ENST00000396846; = p.V5L on NM_001284527.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 118/242 reads (49%) | SIFT tolerated, low confidence (0.33); PolyPhen possibly damaging (0.686); called by muse, mutect2, varscan2
- ACTL7B | c.1194C>A p.V398= | Silent (SNP) | VAF 12/92 reads (13%) | called by muse, mutect2, varscan2
- ADAM29 | c.1143G>A p.R381= | Silent (SNP) | VAF 57/193 reads (30%) | called by muse, mutect2, varscan2
- AHCTF1 | c.2196T>G p.P732= (on ENST00000366508; = p.P706= on NM_015446.5) | Silent (SNP) | VAF 15/40 reads (38%) | called by muse, mutect2, varscan2
- ALG2 | c.420A>T p.P140= | Silent (SNP) | VAF 46/176 reads (26%) | called by muse, mutect2, varscan2
- ANKRD27 | c.2352C>T p.A784= | Silent (SNP) | VAF 11/20 reads (55%) | called by muse, mutect2
- AQR | c.4248C>T p.D1416= | Silent (SNP) | VAF 82/502 reads (16%) | called by muse, mutect2, varscan2
- ATF3 | c.330G>A p.K110= | Silent (SNP) | VAF 21/86 reads (24%) | called by muse, mutect2, varscan2
- CCNK | c.1374C>T p.Y458= | Silent (SNP) | VAF 26/52 reads (50%) | catalogued as rs757619350; called by muse, mutect2, varscan2
- CHD5 | c.4506C>A p.T1502= | Silent (SNP) | VAF 51/132 reads (39%) | catalogued as COSV99312138; called by muse, mutect2, varscan2
- CHRM4 | c.351C>T p.N117= | Silent (SNP) | VAF 90/294 reads (31%) | catalogued as rs200711711, COSV63126667; called by muse, mutect2, varscan2
- CLK3 | c.621G>A p.R207= (on ENST00000395066 / NM_001130028.1; = p.R59= on NM_003992.4) | Silent (SNP) | VAF 8/180 reads (4%) | catalogued as rs1474782450, COSV61414457; called by muse, mutect2
- COL9A1 | c.2106G>A p.K702= | Silent (SNP) | VAF 20/65 reads (31%) | catalogued as rs774146890, COSV57891804; ClinVar: likely benign; called by muse, mutect2, varscan2
- CTAGE1 | c.420C>A p.S140= | Silent (SNP) | VAF 20/270 reads (7%) | catalogued as COSV66942841; called by muse, mutect2
- CTSV | c.570C>A p.V190= | Silent (SNP) | VAF 16/435 reads (4%) | called by muse, mutect2
- CYFIP1 | c.2490C>T p.H830= | Silent (SNP) | VAF 24/309 reads (8%) | called by muse, mutect2
- DIP2C | c.2523G>T p.V841= | Silent (SNP) | VAF 99/329 reads (30%) | catalogued as rs573371081; called by muse, mutect2, varscan2
- ECPAS | c.2424C>T p.C808= | Silent (SNP) | VAF 84/242 reads (35%) | called by muse, mutect2, varscan2
- EPB42 | c.1227C>A p.S409= (on ENST00000441366 / NM_001114134.2; = p.S439= on NM_000119.3) | Silent (SNP) | VAF 40/179 reads (22%) | called by muse, mutect2, varscan2
- ESPL1 | c.3639C>T p.S1213= | Silent (SNP) | VAF 86/203 reads (42%) | catalogued as rs753840797; called by muse, mutect2, varscan2
- F8 | c.6249C>G p.T2083= | Silent (SNP) | VAF 8/99 reads (8%) | catalogued as COSV100811628; called by muse, mutect2
- FBXL17 | c.732C>T p.D244= | Silent (SNP) | VAF 12/28 reads (43%) | called by muse, mutect2, varscan2
- FCRLB | c.1185A>G p.P395= | Silent (SNP) | VAF 163/544 reads (30%) | called by muse, mutect2, varscan2
- FLNC | c.90G>A p.E30= | Silent (SNP) | VAF 14/170 reads (8%) | called by muse, mutect2
- FUBP3 | c.1518G>A p.Q506= | Silent (SNP) | VAF 14/54 reads (26%) | called by muse, mutect2, varscan2
- GEMIN4 | c.1875A>G p.L625= | Silent (SNP) | VAF 57/137 reads (42%) | catalogued as rs1283667429; called by muse, mutect2, varscan2
- GEMIN4 | c.333C>A p.I111= | Silent (SNP) | VAF 107/261 reads (41%) | called by muse, mutect2, varscan2
- GGT6 | c.732C>T p.G244= (on ENST00000574154 / NM_001122890.3; = p.G212= on NM_153338.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 48/117 reads (41%) | catalogued as rs373381271, COSV54593697; called by muse, mutect2, varscan2
- GML | c.88A>C p.R30= | Silent (SNP) | VAF 40/129 reads (31%) | called by muse, mutect2, varscan2
- HEY1 | c.580C>T p.L194= | Silent (SNP) | VAF 55/194 reads (28%) | called by muse, mutect2, varscan2
- HP | c.1068C>T p.G356= | Silent (SNP) | VAF 60/136 reads (44%) | catalogued as rs774808400; called by muse, mutect2, varscan2
- IGKV4-1 | c.177A>G p.L59= | Silent (SNP) | VAF 56/66 reads (85%) | catalogued as rs551368026; called by muse, varscan2
- IRS1 | c.900C>A p.T300= | Silent (SNP) | VAF 22/190 reads (12%) | called by muse, mutect2, varscan2
- ITPRIP | c.1452G>T p.V484= | Silent (SNP) | VAF 26/203 reads (13%) | called by muse, mutect2, varscan2
- KISS1 | c.237G>T p.G79= | Silent (SNP) | VAF 17/89 reads (19%) | called by muse, mutect2, varscan2
- KMT5A | c.981G>A p.A327= | Silent (SNP) | VAF 75/163 reads (46%) | catalogued as rs199916420; called by muse, mutect2, varscan2
- LRP1 | c.7413C>T p.A2471= | Silent (SNP) | VAF 15/26 reads (58%) | called by muse, mutect2, varscan2
- LUC7L | c.171A>T p.G57= | Silent (SNP) | VAF 47/481 reads (10%) | called by muse, mutect2
- MPDU1 | c.576G>T p.L192= | Silent (SNP) | VAF 17/160 reads (11%) | called by muse, mutect2, varscan2
- MR1 | c.633A>G p.K211= | Silent (SNP) | VAF 81/209 reads (39%) | called by muse, mutect2, varscan2
- MUC6 | c.4113C>A p.G1371= | Silent (SNP) | VAF 16/228 reads (7%) | called by muse, mutect2
- MYO7B | c.240C>T p.G80= | Silent (SNP) | VAF 23/213 reads (11%) | called by muse, mutect2, varscan2
- NCMAP | c.120C>A p.V40= | Silent (SNP) | VAF 17/72 reads (24%) | called by muse, mutect2, varscan2
- NEK8 | c.1365G>A p.V455= | Silent (SNP) | VAF 9/102 reads (9%) | called by muse, mutect2
- NSMCE1 | c.744G>A p.E248= | Silent (SNP) | VAF 63/152 reads (41%) | called by muse, mutect2, varscan2
- OGDH | c.564G>A p.L188= | Silent (SNP) | VAF 17/370 reads (5%) | catalogued as rs1179029016; called by muse, mutect2
- PCDHA8 | c.1629G>A p.P543= | Silent (SNP) | VAF 31/53 reads (58%) | catalogued as rs555722520, COSV65333069, COSV65333143; called by muse, mutect2, varscan2
- PHLDB1 | c.2832C>T p.H944= | Silent (SNP) | VAF 27/80 reads (34%) | called by muse, mutect2, varscan2
- PSG8 | c.324G>A p.L108= | Silent (SNP) | VAF 96/303 reads (32%) | catalogued as COSV100126544; called by muse, mutect2, varscan2
- PTCHD4 | c.729G>C p.L243= | Silent (SNP) | VAF 66/225 reads (29%) | called by muse, mutect2, varscan2
- RIMBP2 | c.2748A>T p.A916= | Silent (SNP) | VAF 57/125 reads (46%) | called by muse, mutect2, varscan2
- RSC1A1 | c.1242C>A p.V414= | Silent (SNP) | VAF 20/243 reads (8%) | called by muse, mutect2
- RXFP3 | c.102G>T p.A34= | Silent (SNP) | VAF 69/293 reads (24%) | called by muse, mutect2, varscan2
- SEMA5B | c.213G>T p.L71= | Silent (SNP) | VAF 8/90 reads (9%) | called by muse, mutect2
- SLC16A14 | c.1407A>G p.K469= | Silent (SNP) | VAF 19/57 reads (33%) | called by muse, mutect2, varscan2
- SORBS3 | c.1323G>A p.E441= | Silent (SNP) | VAF 46/113 reads (41%) | called by muse, mutect2, varscan2
- TBK1 | c.900A>T p.A300= | Silent (SNP) | VAF 16/172 reads (9%) | called by muse, mutect2
- TFRC | c.1758G>T p.V586= | Silent (SNP) | VAF 10/207 reads (5%) | called by muse, mutect2
- TMEM151B | c.918G>A p.A306= | Silent (SNP) | VAF 12/277 reads (4%) | catalogued as rs879018632; called by muse, mutect2
- UXS1 | c.585C>T p.A195= | Silent (SNP) | VAF 17/97 reads (18%) | called by muse, mutect2, varscan2
- ZC3H13 | c.3723G>T p.L1241= | Silent (SNP) | VAF 90/99 reads (91%) | called by muse, mutect2, varscan2
- AC108734.4 | n.1765G>T | RNA (SNP) | VAF 15/136 reads (11%) | called by muse, mutect2, varscan2
- ACOT8 | c.262+1341C>A | Intron (SNP) | VAF 24/58 reads (41%) | called by muse, mutect2, varscan2
- AGR2 | c.*139T>A | 3'UTR (SNP) | VAF 7/131 reads (5%) | called by muse, mutect2
- AHSA2P | n.1510C>T | RNA (SNP) | VAF 20/59 reads (34%) | called by muse, mutect2, varscan2
- AIF1L | c.*2453C>T | 3'UTR (SNP) | VAF 34/119 reads (29%) | called by muse, mutect2, varscan2
- ALG10B | c.172-97C>T | Intron (SNP) | VAF 54/164 reads (33%) | called by muse, mutect2, varscan2
- AMD1 | c.*1004G>C | 3'UTR (SNP) | VAF 13/32 reads (41%) | called by muse, mutect2, varscan2
- ANKRD31 | c.104+32C>A | Intron (SNP) | VAF 16/41 reads (39%) | called by muse, mutect2, varscan2
- ARHGEF25 | c.-337G>T | 5'UTR (SNP) | VAF 13/101 reads (13%) | called by muse, mutect2, varscan2
- ARHGEF5 | c.*460C>T | 3'UTR (SNP) | VAF 41/139 reads (29%) | called by muse, mutect2, varscan2
- ARMT1 | chr6:151452261 C>T | 5'Flank (SNP) | VAF 4/33 reads (12%) | called by muse, mutect2
- ATP13A5 | c.2159-21C>A | Intron (SNP) | VAF 36/147 reads (24%) | called by muse, mutect2, varscan2
- B2M | c.*351G>C | 3'UTR (SNP) | VAF 24/106 reads (23%) | called by muse, mutect2, varscan2
- B3GALT6 | c.*1017C>A | 3'UTR (SNP) | VAF 76/273 reads (28%) | called by muse, mutect2, varscan2
- BCAP29 | c.344+102G>A | Intron (SNP) | VAF 4/25 reads (16%) | called by muse, mutect2
- BCL2 | c.*2491A>G | 3'UTR (SNP) | VAF 13/63 reads (21%) | catalogued as rs1009407487; called by muse, mutect2, varscan2
- BNIP2 | c.*3151C>G | 3'UTR (SNP) | VAF 12/205 reads (6%) | called by muse, mutect2
- C22orf39 | c.*2944G>A | 3'UTR (SNP) | VAF 37/103 reads (36%) | called by muse, mutect2, varscan2
- C2orf91 | n.2245A>G | RNA (SNP) | VAF 48/149 reads (32%) | called by muse, mutect2, varscan2
- C7 | c.*547C>A | 3'UTR (SNP) | VAF 12/55 reads (22%) | called by muse, mutect2, varscan2
- CACNA1E | c.*8986C>T | 3'UTR (SNP) | VAF 4/67 reads (6%) | called by muse, mutect2
- CBX8 | c.*603C>T | 3'UTR (SNP) | VAF 18/57 reads (32%) | called by muse, mutect2, varscan2
- CCDC38 | c.37+1533C>T | Intron (SNP) | VAF 7/17 reads (41%) | catalogued as rs1019372914; called by muse, mutect2
- CCNT2 | c.774+138C>T | Intron (SNP) | VAF 42/109 reads (39%) | called by muse, mutect2, varscan2
- CD1D | chr1:158177012 T>A | 5'Flank (SNP) | VAF 20/74 reads (27%) | called by muse, mutect2, varscan2
- CEACAM19 | c.576-98C>A | Intron (SNP) | VAF 10/34 reads (29%) | called by muse, mutect2, varscan2
- CEACAM19 | c.576-97C>A | Intron (SNP) | VAF 10/36 reads (28%) | called by muse, mutect2, varscan2
- CHAF1B | c.*215C>T | 3'UTR (SNP) | VAF 57/92 reads (62%) | catalogued as rs571857716; called by muse, mutect2, varscan2
- CLDN18 | c.*1601C>T | 3'UTR (SNP) | VAF 14/60 reads (23%) | catalogued as rs1002704017; called by muse, mutect2
- COL24A1 | c.*917G>C | 3'UTR (SNP) | VAF 60/117 reads (51%) | catalogued as rs1490456958; called by muse, mutect2, varscan2
- CPED1 | c.*190C>T | 3'UTR (SNP) | VAF 30/80 reads (38%) | called by muse, mutect2, varscan2
- CYFIP2 | chr5:157394442 G>A | 3'Flank (SNP) | VAF 48/149 reads (32%) | called by muse, mutect2, varscan2
- CYP2B7P | n.896G>T | RNA (SNP) | VAF 34/152 reads (22%) | called by muse, mutect2, varscan2
- DBF4B | c.1190-603G>A | Intron (SNP) | VAF 47/130 reads (36%) | called by muse, mutect2, varscan2
- DDX10 | c.2450+847A>G | Intron (SNP) | VAF 17/75 reads (23%) | called by muse, mutect2, varscan2
- DDX19B | c.107-48del | Intron (DEL) | VAF 95/249 reads (38%) | called by mutect2, pindel, varscan2
- DEFB132 | c.*1387G>C | 3'UTR (SNP) | VAF 34/99 reads (34%) | called by muse, mutect2, varscan2
- DENND10 | c.*385G>C | 3'UTR (SNP) | VAF 22/320 reads (7%) | called by muse, mutect2
- DENND5B | c.*4391C>A | 3'UTR (SNP) | VAF 10/115 reads (9%) | called by muse, mutect2
- DFFB | c.*1260A>G | 3'UTR (SNP) | VAF 47/151 reads (31%) | called by muse, mutect2, varscan2
- DLAT | c.*1123T>G | 3'UTR (SNP) | VAF 80/197 reads (41%) | called by muse, mutect2, varscan2
- DMRT1 | c.*721G>A | 3'UTR (SNP) | VAF 5/97 reads (5%) | called by muse, mutect2
- DMTF1 | chr7:87152314 G>C | 5'Flank (SNP) | VAF 65/235 reads (28%) | called by muse, mutect2, varscan2
- DPYSL3 | c.-95C>A | 5'UTR (SNP) | VAF 19/47 reads (40%) | called by muse, mutect2, varscan2
- DUSP7 | c.952+1339G>C | Intron (SNP) | VAF 64/162 reads (40%) | called by muse, mutect2, varscan2
- ELFN2 | c.*141G>A | 3'UTR (SNP) | VAF 4/20 reads (20%) | catalogued as rs897357111, COSV68745260; called by muse, mutect2
- ELP1 | c.650-43A>T | Intron (SNP) | VAF 40/60 reads (67%) | called by muse, mutect2, varscan2
- EMX2 | c.*370G>T | 3'UTR (SNP) | VAF 44/160 reads (28%) | called by muse, mutect2, varscan2
- ETS2 | c.*736G>T | 3'UTR (SNP) | VAF 15/48 reads (31%) | catalogued as rs1016285075; called by muse, mutect2, varscan2
- FAM189A1 | c.*125C>T | 3'UTR (SNP) | VAF 46/240 reads (19%) | called by muse, mutect2, varscan2
- FAM53C | c.*350T>G | 3'UTR (SNP) | VAF 82/176 reads (47%) | called by muse, mutect2, varscan2
- FAM98B | c.*1266_*1278del | 3'UTR (DEL) | VAF 15/150 reads (10%) | called by mutect2, pindel
- FBRSL1 | c.*919G>T | 3'UTR (SNP) | VAF 14/124 reads (11%) | called by muse, mutect2, varscan2
- FBXL21P | n.1119A>G | RNA (SNP) | VAF 54/114 reads (47%) | called by muse, mutect2, varscan2
- FCER1G | c.*43C>T | 3'UTR (SNP) | VAF 147/502 reads (29%) | called by muse, mutect2, varscan2
- FKBP7 | c.*1845dup | 3'UTR (INS) | VAF 46/106 reads (43%) | called by mutect2, varscan2
- FLG | c.*6T>A | 3'UTR (SNP) | VAF 20/521 reads (4%) | called by muse, mutect2
- FOXC2 | c.*237G>A | 3'UTR (SNP) | VAF 5/14 reads (36%) | called by muse, mutect2
- FOXL2NB | c.*954C>T | 3'UTR (SNP) | VAF 61/211 reads (29%) | called by muse, mutect2, varscan2
- FOXRED1 | c.*173C>A | 3'UTR (SNP) | VAF 50/205 reads (24%) | catalogued as rs1478624812; called by muse, mutect2, varscan2
- FSCN3 | c.960+130T>C | Intron (SNP) | VAF 18/51 reads (35%) | called by muse, mutect2, varscan2
- FTO | c.*1800G>A | 3'UTR (SNP) | VAF 9/20 reads (45%) | called by muse, mutect2, varscan2
- FUT4 | c.*417G>A | 3'UTR (SNP) | VAF 13/214 reads (6%) | called by muse, mutect2
- FYB1 | c.*1724G>T | 3'UTR (SNP) | VAF 18/73 reads (25%) | catalogued as rs939662187; called by muse, mutect2, varscan2
- FZD5 | c.*2276del | 3'UTR (DEL) | VAF 26/72 reads (36%) | called by mutect2, pindel, varscan2
- GABARAP | c.-119G>A | 5'UTR (SNP) | VAF 27/65 reads (42%) | catalogued as rs976912366; called by muse, varscan2
- GASK1A | c.-130C>T | 5'UTR (SNP) | VAF 60/124 reads (48%) | called by mutect2, varscan2
- GCKR | c.969-44T>C | Intron (SNP) | VAF 28/280 reads (10%) | called by muse, mutect2, varscan2
- GFOD1 | c.*6804C>T | 3'UTR (SNP) | VAF 53/247 reads (21%) | called by muse, mutect2, varscan2
- GNAI2 | c.*656G>C | 3'UTR (SNP) | VAF 10/121 reads (8%) | called by muse, mutect2
- GNB5 | c.864-10C>T | Intron (SNP) | VAF 18/165 reads (11%) | catalogued as rs151089434; called by muse, mutect2
- GPX2 | chr14:64944476 G>A | 5'Flank (SNP) | VAF 27/62 reads (44%) | called by muse, mutect2, varscan2
- GTDC1 | c.180-147C>A | Intron (SNP) | VAF 4/14 reads (29%) | called by mutect2, varscan2
- GUCY1A1 | c.*1797C>A | 3'UTR (SNP) | VAF 28/68 reads (41%) | called by muse, mutect2, varscan2
- GUF1 | c.*374C>A | 3'UTR (SNP) | VAF 8/66 reads (12%) | called by muse, mutect2, varscan2
- GULP1 | c.399+50G>T | Intron (SNP) | VAF 28/73 reads (38%) | called by muse, mutect2, varscan2
- HAS3 | c.*2398C>G | 3'UTR (SNP) | VAF 17/97 reads (18%) | called by muse, mutect2, varscan2
- HGSNAT | c.*3211C>A | 3'UTR (SNP) | VAF 25/86 reads (29%) | called by muse, mutect2, varscan2
- HGSNAT | c.*3212C>A | 3'UTR (SNP) | VAF 24/85 reads (28%) | called by muse, mutect2, varscan2
- HIPK3 | c.*1434T>A | 3'UTR (SNP) | VAF 12/152 reads (8%) | called by muse, mutect2
- HMGCLL1 | c.*657T>A | 3'UTR (SNP) | VAF 32/117 reads (27%) | catalogued as rs929250304; called by muse, mutect2, varscan2
- HSBP1L1 | c.118+154A>C | Intron (SNP) | VAF 11/38 reads (29%) | called by muse, mutect2
- HSPA12A | c.*2684A>T | 3'UTR (SNP) | VAF 29/104 reads (28%) | called by muse, mutect2, varscan2
- IFIT5 | c.*1184T>A | 3'UTR (SNP) | VAF 39/79 reads (49%) | called by muse, mutect2, varscan2
- IGHV3-23 | c.-75C>T | 5'UTR (SNP) | VAF 12/45 reads (27%) | called by muse, mutect2, varscan2
- IQCE | c.*2346G>T | 3'UTR (SNP) | VAF 37/161 reads (23%) | called by muse, mutect2, varscan2
- ITGAL | c.3229-65A>T | Intron (SNP) | VAF 46/143 reads (32%) | called by muse, mutect2, varscan2
- ITGB5 | c.*1178G>T | 3'UTR (SNP) | VAF 16/131 reads (12%) | called by muse, mutect2, varscan2
- KANSL1 | c.1289+63A>T | Intron (SNP) | VAF 29/125 reads (23%) | called by muse, mutect2, varscan2
- KBTBD12 | c.*3366G>A | 3'UTR (SNP) | VAF 13/40 reads (33%) | called by muse, mutect2
- KBTBD4 | c.*128C>T | 3'UTR (SNP) | VAF 20/72 reads (28%) | called by muse, mutect2, varscan2
- KCNQ2 | c.1247+150C>T | Intron (SNP) | VAF 12/252 reads (5%) | called by muse, mutect2
- KLHDC7A | c.*170G>A | 3'UTR (SNP) | VAF 10/218 reads (5%) | called by muse, mutect2
- KLHDC7B | c.*435G>C | 3'UTR (SNP) | VAF 15/122 reads (12%) | called by muse, mutect2, varscan2
- KLRB1 | c.*50T>C | 3'UTR (SNP) | VAF 21/246 reads (9%) | catalogued as COSV99987208; called by muse, mutect2
- LINC02412 | n.1277T>A | RNA (SNP) | VAF 5/45 reads (11%) | called by muse, mutect2, varscan2
- LINS1 | c.*1344G>A | 3'UTR (SNP) | VAF 7/148 reads (5%) | called by muse, mutect2
- LPCAT4 | c.*272C>T | 3'UTR (SNP) | VAF 4/75 reads (5%) | catalogued as rs1013327401; called by muse, mutect2
- LPIN2 | c.*1607A>T | 3'UTR (SNP) | VAF 27/119 reads (23%) | called by muse, mutect2, varscan2
- LRATD1 | c.*4804T>A | 3'UTR (SNP) | VAF 10/139 reads (7%) | called by muse, mutect2
- LRP8 | c.*805A>T | 3'UTR (SNP) | VAF 13/110 reads (12%) | called by muse, mutect2, varscan2
- LRRC15 | c.*1873_*1879del | 3'UTR (DEL) | VAF 52/188 reads (28%) | called by mutect2, pindel, varscan2
- LUZP2 | c.*3058A>T | 3'UTR (SNP) | VAF 15/56 reads (27%) | called by muse, mutect2, varscan2
- LY6G5C | c.346-885C>T | Intron (SNP) | VAF 83/272 reads (31%) | called by muse, mutect2, varscan2
- MACC1 | chr7:20139144 G>C | 3'Flank (SNP) | VAF 63/200 reads (32%) | called by muse, mutect2, varscan2
- MAN2B2 | c.*374T>G | 3'UTR (SNP) | VAF 27/197 reads (14%) | called by muse, mutect2, varscan2
- MAP4 | c.1999+4309A>G | Intron (SNP) | VAF 75/257 reads (29%) | called by muse, mutect2, varscan2
- MATR3 | c.-157_-155del | 5'UTR (DEL) | VAF 20/46 reads (43%) | called by mutect2, pindel, varscan2
- MAU2 | c.*137C>G | 3'UTR (SNP) | VAF 130/449 reads (29%) | called by muse, mutect2, varscan2
- MFN2 | c.709-42C>A | Intron (SNP) | VAF 84/303 reads (28%) | catalogued as rs1181707568; called by muse, varscan2
- MGAT1 | c.*147T>C | 3'UTR (SNP) | VAF 12/160 reads (8%) | catalogued as rs1198712096; called by muse, mutect2
- MRPL30 | c.*1379C>T | 3'UTR (SNP) | VAF 3/48 reads (6%) | called by muse, mutect2
- MS4A14 | c.267+68T>A | Intron (SNP) | VAF 5/56 reads (9%) | called by muse, mutect2
- MTBP | chr8:120445371 T>G | 5'Flank (SNP) | VAF 23/66 reads (35%) | called by muse, mutect2, varscan2
- MTRF1L | c.*2484del | 3'UTR (DEL) | VAF 131/371 reads (35%) | called by mutect2, pindel, varscan2
- MVB12B | c.*2383G>T | 3'UTR (SNP) | VAF 49/71 reads (69%) | called by muse, mutect2, varscan2
- MYO16 | c.*936G>A | 3'UTR (SNP) | VAF 7/139 reads (5%) | catalogued as rs1424079552; called by muse, mutect2
- MYO3A | c.732-599C>T | Intron (SNP) | VAF 37/146 reads (25%) | called by muse, mutect2, varscan2
- NDST1 | c.*3186C>T | 3'UTR (SNP) | VAF 32/73 reads (44%) | called by muse, mutect2, varscan2
- NHLH2 | c.-8-745C>T | Intron (SNP) | VAF 18/195 reads (9%) | called by muse, mutect2
- NLRP2 | c.*179T>A | 3'UTR (SNP) | VAF 7/76 reads (9%) | called by muse, mutect2
- NSD2 | c.2014-52G>A | Intron (SNP) | VAF 37/100 reads (37%) | called by muse, mutect2, varscan2
- NSF | c.*747A>T | 3'UTR (SNP) | VAF 17/119 reads (14%) | called by muse, mutect2, varscan2
- ONECUT2 | c.*11750dup | 3'UTR (INS) | VAF 16/63 reads (25%) | called by mutect2, varscan2
- OR7E24 | c.*5G>T | 3'UTR (SNP) | VAF 40/335 reads (12%) | called by muse, mutect2, varscan2
- PAK1IP1 | c.-7C>G | 5'UTR (SNP) | VAF 76/324 reads (23%) | called by muse, mutect2, varscan2
- PAPOLA | c.910-58G>T | Intron (SNP) | VAF 3/36 reads (8%) | called by muse, mutect2
- PAPOLB | c.*1233A>G | 3'UTR (SNP) | VAF 53/159 reads (33%) | called by muse, mutect2, varscan2
- PAQR6 | c.760+39G>A | Intron (SNP) | VAF 52/242 reads (21%) | called by muse, mutect2, varscan2
- PARP8 | c.*400T>A | 3'UTR (SNP) | VAF 26/100 reads (26%) | called by muse, mutect2, varscan2
- PAWR | c.*5262T>C | 3'UTR (SNP) | VAF 9/77 reads (12%) | called by muse, mutect2, varscan2
- PDE4D | c.456-59882C>A | Intron (SNP) | VAF 57/142 reads (40%) | called by muse, mutect2, varscan2
- PDIA4 | c.*590G>A | 3'UTR (SNP) | VAF 53/176 reads (30%) | called by muse, mutect2, varscan2
- PDZRN4 | c.*106_*109del | 3'UTR (DEL) | VAF 75/246 reads (30%) | called by mutect2, pindel, varscan2
- PEG10 | c.*4798G>T | 3'UTR (SNP) | VAF 35/107 reads (33%) | called by muse, mutect2, varscan2
- PIK3R3 | c.*3382T>C | 3'UTR (SNP) | VAF 34/82 reads (41%) | called by muse, mutect2, varscan2
- PKNOX2 | c.*66G>A | 3'UTR (SNP) | VAF 31/120 reads (26%) | catalogued as rs879203288, COSV100021397; called by muse, mutect2, varscan2
- PLCD3 | c.1712-58G>C | Intron (SNP) | VAF 10/19 reads (53%) | called by muse, mutect2, varscan2
- PLOD2 | c.*89G>A | 3'UTR (SNP) | VAF 22/70 reads (31%) | called by muse, mutect2, varscan2
- POU2AF1 | c.*1248C>T | 3'UTR (SNP) | VAF 12/68 reads (18%) | catalogued as rs376428762; called by muse, varscan2
- POU2F1 | c.*10708G>T | 3'UTR (SNP) | VAF 10/198 reads (5%) | called by muse, mutect2
- PPM1L | c.*589C>G | 3'UTR (SNP) | VAF 6/140 reads (4%) | called by muse, mutect2
- PPP1R9A | c.*2792A>G | 3'UTR (SNP) | VAF 16/48 reads (33%) | catalogued as rs964246763; called by muse, mutect2, varscan2
- PRKD1 | c.*714T>C | 3'UTR (SNP) | VAF 14/34 reads (41%) | called by muse, mutect2, varscan2
- PRKRIP1 | c.*1307C>G | 3'UTR (SNP) | VAF 23/230 reads (10%) | called by muse, mutect2
- PSMG4 | c.251-1210T>C | Intron (SNP) | VAF 71/274 reads (26%) | called by muse, mutect2, varscan2
- PTEN | c.*3989G>T | 3'UTR (SNP) | VAF 28/74 reads (38%) | called by muse, mutect2, varscan2
- PTGR1 | c.209+194C>A | Intron (SNP) | VAF 67/355 reads (19%) | called by muse, mutect2, varscan2
- PXDN | c.1947-110del | Intron (DEL) | VAF 17/47 reads (36%) | called by mutect2, pindel, varscan2
- RAB40C | c.*1402G>A | 3'UTR (SNP) | VAF 15/145 reads (10%) | called by muse, mutect2, varscan2
- RBM24 | c.169-435G>T | Intron (SNP) | VAF 49/184 reads (27%) | called by muse, mutect2, varscan2
- RFC2 | c.*254T>G | 3'UTR (SNP) | VAF 4/17 reads (24%) | called by muse, mutect2, varscan2
- RGS16 | c.*1606A>C | 3'UTR (SNP) | VAF 7/58 reads (12%) | called by muse, mutect2, varscan2
- RPS27 | c.116-44_116-43dup | Intron (INS) | VAF 43/160 reads (27%) | called by mutect2, pindel, varscan2
- RRM2B | c.*1033del | 3'UTR (DEL) | VAF 31/132 reads (23%) | called by mutect2, pindel, varscan2
- RTN3 | c.*532T>C | 3'UTR (SNP) | VAF 47/345 reads (14%) | called by muse, mutect2, varscan2
- RUFY3 | c.*1295T>G | 3'UTR (SNP) | VAF 7/32 reads (22%) | catalogued as rs961617856; called by muse, mutect2, varscan2
- SCN5A | c.*9C>A | 3'UTR (SNP) | VAF 11/64 reads (17%) | catalogued as COSV100346771; called by muse, mutect2, varscan2
- SESN3 | c.*5181A>G | 3'UTR (SNP) | VAF 29/98 reads (30%) | called by muse, mutect2, varscan2
- SEZ6L | c.*1346C>G | 3'UTR (SNP) | VAF 17/106 reads (16%) | called by muse, mutect2, varscan2
- SGK1 | c.-266C>A | 5'UTR (SNP) | VAF 79/167 reads (47%) | called by muse, mutect2, varscan2
- SH3TC1 | c.173-38T>G | Intron (SNP) | VAF 25/218 reads (11%) | catalogued as rs1411205587; called by muse, mutect2, varscan2
- SKP1 | c.457-241G>A | Intron (SNP) | VAF 98/241 reads (41%) | called by muse, mutect2, varscan2
- SLC30A7 | c.-2_1del | 5'UTR (DEL) | VAF 92/233 reads (39%) | catalogued as rs976431646; called by pindel, varscan2
- SLC44A1 | c.*5794C>T | 3'UTR (SNP) | VAF 69/214 reads (32%) | catalogued as rs886283955; called by muse, mutect2, varscan2
- SLC5A12 | c.1153+726T>G | Intron (SNP) | VAF 51/90 reads (57%) | called by muse, mutect2, varscan2
- SMAD9 | c.*2054C>T | 3'UTR (SNP) | VAF 36/39 reads (92%) | called by muse, mutect2, varscan2
- SMARCAD1 | c.*28G>A | 3'UTR (SNP) | VAF 50/176 reads (28%) | catalogued as rs1255919349; called by muse, varscan2
- SMTN | c.-80-207C>T | Intron (SNP) | VAF 10/82 reads (12%) | called by muse, mutect2, varscan2
- SMU1 | c.-34G>C | 5'UTR (SNP) | VAF 182/528 reads (34%) | called by muse, varscan2
- SMUG1 | c.285+507G>C | Intron (SNP) | VAF 51/140 reads (36%) | called by muse, mutect2, varscan2
- SNX15 | c.*642G>T | 3'UTR (SNP) | VAF 12/45 reads (27%) | called by muse, mutect2, varscan2
- SNX20 | chr16:50667419 C>A | 3'Flank (SNP) | VAF 85/239 reads (36%) | called by muse, mutect2, varscan2
- SOX2 | c.-33C>T | 5'UTR (SNP) | VAF 28/79 reads (35%) | called by muse, mutect2, varscan2
- SP7 | c.*937C>T | 3'UTR (SNP) | VAF 37/101 reads (37%) | called by muse, mutect2, varscan2
- SPATA8 | n.259C>A | RNA (SNP) | VAF 32/98 reads (33%) | called by muse, mutect2, varscan2
- SPICE1 | c.*1336G>T | 3'UTR (SNP) | VAF 25/80 reads (31%) | called by muse, mutect2, varscan2
- SPOP | c.*1349G>T | 3'UTR (SNP) | VAF 5/47 reads (11%) | called by muse, mutect2, varscan2
- SPX | c.*128C>T | 3'UTR (SNP) | VAF 77/184 reads (42%) | called by muse, mutect2, varscan2
- SRPRA | c.365+14C>G | Intron (SNP) | VAF 56/129 reads (43%) | called by muse, mutect2, varscan2
- ST3GAL3 | c.348-14974A>C | Intron (SNP) | VAF 11/96 reads (11%) | called by muse, mutect2, varscan2
- ST3GAL4 | c.*120G>A | 3'UTR (SNP) | VAF 10/142 reads (7%) | called by muse, mutect2
- STEAP4 | c.*3307T>A | 3'UTR (SNP) | VAF 7/139 reads (5%) | called by muse, mutect2
- SYT10 | c.*124G>A | 3'UTR (SNP) | VAF 29/129 reads (22%) | called by muse, mutect2
- TAS2R9 | c.-87G>C | 5'UTR (SNP) | VAF 32/71 reads (45%) | called by muse, mutect2, varscan2
- TBC1D22A | c.*1724G>A | 3'UTR (SNP) | VAF 8/144 reads (6%) | called by muse, mutect2
- TBX2 | chr17:61412195 G>T | 3'Flank (SNP) | VAF 16/101 reads (16%) | called by muse, mutect2, varscan2
- TCP10L3 | n.2618+454A>C | Intron (SNP) | VAF 28/86 reads (33%) | called by muse, varscan2
- TFEC | c.*656A>C | 3'UTR (SNP) | VAF 29/101 reads (29%) | called by muse, mutect2, varscan2
- THY1 | c.*1002C>T | 3'UTR (SNP) | VAF 24/272 reads (9%) | catalogued as rs1565325603; called by muse, mutect2
- TMEM109 | c.*222T>G | 3'UTR (SNP) | VAF 78/278 reads (28%) | catalogued as rs1417820397; called by muse, mutect2, varscan2
- TMEM132D | c.-48G>A | 5'UTR (SNP) | VAF 37/66 reads (56%) | called by muse, mutect2, varscan2
- TMEM170B | c.-33del | 5'UTR (DEL) | VAF 14/58 reads (24%) | called by mutect2, pindel
- TMEM45B | c.*144C>A | 3'UTR (SNP) | VAF 4/73 reads (5%) | called by muse, mutect2
- TMPRSS4 | c.43+72A>C | Intron (SNP) | VAF 11/116 reads (9%) | called by muse, mutect2
- TMTC4 | c.778-75G>T | Intron (SNP) | VAF 81/91 reads (89%) | called by muse, mutect2, varscan2
- TPD52L3 | c.*1321G>T | 3'UTR (SNP) | VAF 29/94 reads (31%) | called by muse, mutect2, varscan2
- TPRG1 | c.*1454T>A | 3'UTR (SNP) | VAF 7/132 reads (5%) | called by muse, mutect2
- TRAK1 | c.1963+638G>A | Intron (SNP) | VAF 37/118 reads (31%) | called by muse, mutect2, varscan2
- TREML2 | c.*1159T>A | 3'UTR (SNP) | VAF 14/134 reads (10%) | called by muse, mutect2
- TRIM24 | c.*162T>C | 3'UTR (SNP) | VAF 19/54 reads (35%) | called by muse, mutect2, varscan2
- TRPV3 | c.*1542C>T | 3'UTR (SNP) | VAF 30/76 reads (39%) | called by muse, mutect2
- TRUB1 | c.*119A>T | 3'UTR (SNP) | VAF 6/66 reads (9%) | called by muse, mutect2
- TSC1 | c.*3619G>T | 3'UTR (SNP) | VAF 84/280 reads (30%) | called by muse, mutect2, varscan2
- TSNARE1 | c.1446+3269T>A | Intron (SNP) | VAF 5/94 reads (5%) | called by muse, mutect2
- TTL | c.*2829_*2831delinsAA | 3'UTR (DEL) | VAF 56/211 reads (27%) | called by pindel, varscan2*
- UNC45B | c.*1418T>A | 3'UTR (SNP) | VAF 10/114 reads (9%) | called by muse, mutect2
- UQCRH | c.*26C>T | 3'UTR (SNP) | VAF 109/265 reads (41%) | catalogued as rs989359535; called by muse, mutect2, varscan2
- USF3 | c.*5843C>T | 3'UTR (SNP) | VAF 20/68 reads (29%) | catalogued as rs1158333276; called by muse, mutect2, varscan2
- USF3 | c.*5592G>C | 3'UTR (SNP) | VAF 60/184 reads (33%) | catalogued as rs1376797461; called by muse, mutect2, varscan2
- UVSSA | c.*7603G>A | 3'UTR (SNP) | VAF 15/27 reads (56%) | called by muse, mutect2, varscan2
- Unknown | chr7:55707300 G>T | IGR (SNP) | VAF 57/345 reads (17%) | called by muse, mutect2, varscan2
- VGLL3 | c.*3330G>A | 3'UTR (SNP) | VAF 23/66 reads (35%) | called by muse, mutect2, varscan2
- WBP2NL | c.*129G>A | 3'UTR (SNP) | VAF 23/179 reads (13%) | called by muse, mutect2, varscan2
- WDR45B | chr17:82648459 C>T | 5'Flank (SNP) | VAF 5/11 reads (45%) | called by muse, mutect2, varscan2
- XCL1 | c.*624del | 3'UTR (DEL) | VAF 70/181 reads (39%) | called by mutect2, pindel, varscan2
- YAF2 | c.152+119G>A | Intron (SNP) | VAF 3/24 reads (13%) | called by muse, mutect2
- YARS1 | c.*558C>T | 3'UTR (SNP) | VAF 83/157 reads (53%) | called by muse, mutect2, varscan2
- ZNF205 | c.*175A>C | 3'UTR (SNP) | VAF 6/106 reads (6%) | called by muse, mutect2
- ZNF26 | c.-270G>A | 5'UTR (SNP) | VAF 21/135 reads (16%) | called by muse, mutect2, varscan2
- ZNF700 | c.*497G>T | 3'UTR (SNP) | VAF 27/85 reads (32%) | called by muse, mutect2, varscan2
- ZNF80 | c.*614C>T | 3'UTR (SNP) | VAF 9/161 reads (6%) | called by muse, mutect2
- ZNF813 | c.*3433T>A | 3'UTR (SNP) | VAF 13/110 reads (12%) | called by muse, mutect2, varscan2
- ZNF861P | n.461A>T | RNA (SNP) | VAF 8/197 reads (4%) | called by muse, mutect2
- ZSCAN29 | c.*2276C>T | 3'UTR (SNP) | VAF 57/213 reads (27%) | called by muse, mutect2, varscan2
